Somatic mutation profile of tumor specimen C3N-07000-01 (aliquot CPT0470770006) from CPTAC case C3N-07000, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 52.2 years (19,084 days).
Specimen C3N-07000-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e534855b-9971-48d3-a62d-55d53877c415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-07000-31 (Blood Derived Normal), aliquot CPT0470860006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49cd152b-66ec-407b-a6df-5abb3782829e

The open-access MAF lists 1,014 somatic variants for this specimen: 630 protein-altering or splice-affecting, 344 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 574, Silent 344, Nonsense Mutation 38, Intron 27, Splice Site 6, Splice Region 5, Frame Shift Del 4, 3'UTR 4, RNA 3, 5'UTR 3, 5'Flank 2, In Frame Del 1.

Variants (750 of 1,014; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CFTR | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756206533, CM994784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A5 | c.1196C>T p.S399L (on ENST00000454036 / NM_001134771.2; = p.S376L on NM_020708.5) | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs1568862550, COSV54787923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2554C>T p.R852* | Nonsense Mutation (SNP) | VAF 57/210 reads (27%) | catalogued as rs869025588, CM161659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150516280; called by muse, mutect2, varscan2
- ABCG8 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as rs771591850; called by muse, mutect2
- ADAMTS10 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.912); catalogued as rs550588972, COSV54356410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY5 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59199304; called by muse, mutect2, varscan2
- ADGRB3 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235597; called by muse, mutect2
- ADGRG3 | c.1165C>T p.L389= | Splice Region (SNP) | VAF 34/269 reads (13%) | catalogued as rs1371201906; called by muse, mutect2, varscan2
- ADGRV1 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67984627, COSV67987315; called by muse, mutect2, varscan2
- AFM | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs781660797, COSV56920526, COSV56922687; called by muse, mutect2
- AFP | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as rs754667512, COSV56927239; called by muse, mutect2, varscan2
- AGBL1 | c.2576G>A p.G859E | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66877601; called by muse, mutect2, varscan2
- AGFG2 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as rs1284345329; called by muse, mutect2, varscan2
- AK5 | c.868C>T p.Q290* (on ENST00000354567 / NM_174858.3; = p.Q264* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 54/301 reads (18%) | catalogued as rs755762619; called by muse, mutect2, varscan2
- AKAP9 | c.3589G>T p.E1197* | Nonsense Mutation (SNP) | VAF 29/247 reads (12%) | catalogued as COSV62339581; called by muse, mutect2, varscan2
- ALPK2 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150536488, COSV64493390; called by muse, mutect2, varscan2
- AMH | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 62/503 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs778071215; called by muse, mutect2, varscan2
- ANKRD60 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.552); catalogued as COSV64518267, COSV64518396; called by muse, mutect2
- ANO2 | c.1667G>A p.R556Q (on ENST00000356134 / NM_001278597.3; = p.R560Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs773771654, COSV59020666; called by muse, mutect2, varscan2
- ARAP2 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 40/468 reads (9%) | catalogued as rs868517624, COSV58282896; called by muse, mutect2
- ARHGEF15 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1278904038; called by muse, mutect2, varscan2
- ASXL3 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV52464752; called by muse, mutect2, varscan2
- ATP2B3 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs201426629; called by muse, mutect2, varscan2
- B3GNT3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs182226982, COSV100592874; called by muse, mutect2, varscan2
- BMP5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702532, COSV63706127; called by muse, mutect2, varscan2
- BNIP5 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367828118; called by muse, varscan2
- C1QTNF3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV99180736; called by muse, mutect2, varscan2
- C1orf50 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65308089; called by muse, mutect2, varscan2
- CA3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs557237110, COSV53409536, COSV53411192; called by muse, mutect2, varscan2
- CACNA1A | c.4993C>T p.L1665F | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV104420573; called by muse, mutect2, varscan2
- CACNA1E | c.3615G>A p.M1205I | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV62420617, COSV62432404; called by muse, mutect2, varscan2
- CACNA1E | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV62394300; called by muse, mutect2
- CAPN13 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99701285; called by muse, mutect2
- CARD18 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 27/390 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.326); catalogued as COSV101596041; called by muse, mutect2
- CARMIL3 | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 54/399 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs769682852; called by muse, mutect2, varscan2
- CCDC39 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as rs540660862, COSV56479847, COSV56482766, COSV56484585; called by muse, mutect2
- CD160 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1461357699; called by muse, mutect2, varscan2
- CEP112 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1238778324, COSV67139641; called by muse, mutect2, varscan2
- CHIA | c.934A>C p.N312H (on ENST00000343320; = p.N204H on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs759836972; called by muse, mutect2, varscan2
- CMYA5 | c.5942C>T p.S1981F | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV71406656; called by muse, mutect2, varscan2
- CNKSR3 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs769891155, COSV101401272; called by muse, mutect2, varscan2
- CNTN6 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV100611942; called by muse, mutect2
- CNTNAP2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769071764, COSV62144657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTRL | c.6155G>A p.R2052K | Missense Mutation (SNP) | VAF 18/469 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53043399; called by muse, mutect2
- COL11A1 | c.4466G>A p.G1489E | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62182079; called by mutect2, varscan2
- COL11A1 | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV62183742; called by mutect2, varscan2
- COL4A4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61637421; called by muse, mutect2, varscan2
- COL4A6 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157582065; called by muse, mutect2, varscan2
- COL5A1 | c.3622C>T p.L1208F | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs863223450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 34/439 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.939); catalogued as COSV62018544; called by muse, mutect2
- CPT1C | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 25/318 reads (8%) | catalogued as COSV54920949; called by muse, mutect2
- CPT1C | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1206306340, COSV54922387; called by muse, mutect2, varscan2
- CSMD1 | c.8156G>A p.R2719K (on ENST00000520002; = p.R2718K on NM_033225.6) | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs182199755, COSV100141384; called by muse, mutect2, varscan2
- CSMD1 | c.2653C>T p.R885C (on ENST00000520002; = p.R884C on NM_033225.6) | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310702695, COSV59352917, COSV99064856; called by muse, mutect2
- CTTNBP2 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1283673575; called by muse, mutect2, varscan2
- CUBN | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs1252344092, COSV100912011, COSV64708251; called by muse, mutect2, varscan2
- CXCL17 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs781054029; called by muse, mutect2
- CYP20A1 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1019481726; called by muse, mutect2
- CYP46A1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419943404, COSV55896247; called by muse, mutect2, varscan2
- DISP2 | c.3790C>T p.P1264S | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.329); catalogued as rs769536187; called by muse, mutect2, varscan2
- DNAH10 | c.2639G>A p.R880Q (on ENST00000409039; = p.R819Q on NM_207437.3) | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs143421929; called by muse, mutect2
- DNAH3 | c.8341G>A p.D2781N | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774722876, COSV54517557; called by muse, mutect2, varscan2
- DNAH5 | c.9928C>T p.R3310C | Missense Mutation (SNP) | VAF 132/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs900076362, COSV54204182; called by muse, mutect2, varscan2
- DNAH7 | c.9325G>A p.G3109R | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56785272; called by muse, mutect2
- DNAH7 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 27/376 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs755754642; called by muse, mutect2
- DNAJC21 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.044); catalogued as rs1208669621, COSV57761174; called by muse, mutect2, varscan2
- DNTT | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.595); catalogued as rs764493303; called by muse, mutect2
- DPPA3 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61502910; called by muse, mutect2
- DSC3 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 50/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs267605140, COSV64572327; called by muse, mutect2, varscan2
- DSCAM | c.2367G>A p.M789I | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV68021463; called by muse, mutect2, varscan2
- DSG4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57390122; called by muse, mutect2
- EHHADH | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 73/349 reads (21%) | catalogued as rs1306718370; called by muse, mutect2, varscan2
- EHMT2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 88/632 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs780407715; called by muse, mutect2, varscan2
- ELOA2 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.834); catalogued as COSV55298915; called by muse, mutect2, varscan2
- EML6 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774245505; called by muse, mutect2
- ENPP5 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs868256108; called by muse, mutect2, varscan2
- EPHA6 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67560246; called by muse, mutect2
- EPHA7 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 34/314 reads (11%) | catalogued as rs749418654, COSV65168614; called by muse, mutect2, varscan2
- ERBB4 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 26/437 reads (6%) | catalogued as COSV61482964; called by muse, mutect2
- ERICH5 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV59316737; called by muse, mutect2, varscan2
- ERV3-1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.266); catalogued as rs1180207272; called by muse, mutect2
- EXPH5 | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs749623073; called by muse, mutect2
- F5 | c.3668C>T p.S1223F | Missense Mutation (SNP) | VAF 42/552 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV63130136; called by muse, mutect2
- FAM133A | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1041921317, COSV59074597; called by muse, mutect2, varscan2
- FAM170A | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs751977810, COSV100089450; called by muse, mutect2
- FAM216B | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV58270103; called by muse, mutect2, varscan2
- FAM53C | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.961); catalogued as rs753315065; called by muse, mutect2, varscan2
- FANCM | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1462865463; called by muse, mutect2, varscan2
- FBN2 | c.6583C>T p.R2195C | Missense Mutation (SNP) | VAF 58/401 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs886059896, COSV52511930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO21 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57972065; called by muse, mutect2
- FBXO41 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1486948491; called by muse, mutect2
- FER1L6 | c.3436G>A p.V1146M | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV67548855; called by muse, mutect2
- FER1L6 | c.3956G>A p.G1319E | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67549400; called by muse, mutect2, varscan2
- FERMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144791466; called by muse, mutect2
- FREM2 | c.8462C>G p.P2821R | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99746669; called by muse, mutect2
- FRMPD2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1445069127, COSV59715849; called by muse, mutect2
- FSHR | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.072); catalogued as COSV58621462; called by muse, mutect2
- FSIP2 | c.1271T>A p.I424N | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100555214; called by muse, mutect2
- GDAP1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 32/262 reads (12%) | catalogued as CM081280, COSV55185255; called by muse, mutect2, varscan2
- GFY | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs552379966; called by muse, mutect2, varscan2
- GJA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 65/441 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as CD163653, COSV53788600, COSV53789126, COSV99569681; called by muse, mutect2, varscan2
- GJB4 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 50/330 reads (15%) | catalogued as COSV100258458; called by muse, mutect2, varscan2
- GPATCH8 | c.120+1G>A p.X40_splice | Splice Site (SNP) | VAF 30/267 reads (11%) | catalogued as rs1198222396, COSV71283382, COSV71284735; called by muse, mutect2, varscan2
- GPD1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs765179111; called by muse, mutect2, varscan2
- GPR158 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs754011154, COSV66269380; called by muse, mutect2
- GPR31 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs765259668; called by muse, mutect2, varscan2
- GPR35 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs145091313; called by muse, mutect2
- GRAMD1B | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1233169320, COSV59203826; called by muse, mutect2, varscan2
- GRAMD2A | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as COSV59033144; called by muse, mutect2, varscan2
- GZMK | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs753500430, COSV50245500; called by muse, mutect2, varscan2
- HIPK3 | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs760055119; called by muse, mutect2
- HP1BP3 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56564436; called by muse, mutect2, varscan2
- HS3ST4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 45/391 reads (12%) | catalogued as rs267604480, COSV58812934, COSV58826059; called by muse, mutect2, varscan2
- HTR1D | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1230225270; called by muse, mutect2, varscan2
- HTR1F | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60388925; called by muse, mutect2, varscan2
- HTR4 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147173991; called by muse, mutect2
- HYDIN | c.11306G>A p.R3769Q | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs772896642, COSV66640624; called by muse, mutect2, varscan2
- HYDIN | c.7201G>A p.E2401K | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs772680657, COSV59250071; called by muse, mutect2, varscan2
- IFT140 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs751323480, CM1511890, COSV54153709; called by muse, mutect2, varscan2
- IGKV6D-41 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781661620; called by muse, mutect2
- IGLL5 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.03); catalogued as rs1485549725, COSV104440293; called by muse, mutect2, varscan2
- IGLV3-12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs774544303; called by muse, mutect2, varscan2
- IGSF10 | c.6304G>A p.G2102R | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138856486; called by muse, mutect2, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- IMPG2 | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51986576; called by muse, mutect2
- INCENP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1279589271; called by muse, mutect2, varscan2
- INSL3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs751299877, COSV57953754; called by muse, mutect2, varscan2
- INTU | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV99611457; called by muse, mutect2
- IPP | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs762267700; called by muse, varscan2
- KATNIP | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 57/451 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55191151; called by muse, mutect2, varscan2
- KCND3 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs925278236; called by muse, mutect2
- KCNH5 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59777625; called by muse, mutect2, varscan2
- KCNMA1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54287097; called by muse, mutect2
- KCNT2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV54062653; called by muse, mutect2, varscan2
- KDM4C | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747465304; called by muse, mutect2, varscan2
- KIAA0513 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 43/265 reads (16%) | catalogued as rs867351382, COSV50742281; called by muse, mutect2, varscan2
- KIF1B | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV55804060; called by muse, mutect2, varscan2
- KMT2A | c.4396C>T p.P1466S | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63282023; called by muse, varscan2
- KRT6B | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 76/733 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884893; called by muse, mutect2, varscan2
- KRT74 | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs192063771; called by muse, mutect2, varscan2
- KRT9 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 31/313 reads (10%) | PolyPhen benign (0.013); catalogued as COSV55851549; called by muse, mutect2
- KRT9 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 30/317 reads (9%) | PolyPhen benign (0.012); catalogued as rs765577453, COSV55852582; called by muse, mutect2
- LAMA2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM973262; called by muse, mutect2, varscan2
- LAMC3 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100736091; called by muse, mutect2
- LOXL2 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 43/289 reads (15%) | catalogued as rs540457123, COSV101207923; called by muse, mutect2, varscan2
- LRP1B | c.9037G>A p.E3013K | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs763519029, COSV67281245, COSV67284862; called by muse, mutect2, varscan2
- LRRC30 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67301970; called by muse, mutect2, varscan2
- LRRC7 | c.3704G>A p.R1235K (on ENST00000651989 / NM_001370785.2; = p.R1202K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50413693, COSV99230483; called by muse, mutect2, varscan2
- LUZP2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1416888159, COSV61196655; called by muse, mutect2, varscan2
- MACROD2 | c.1118C>T p.S373L (on ENST00000642719; = p.S345L on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1328446676, COSV54055814; called by muse, mutect2, varscan2
- MAGEC1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53569247; called by muse, mutect2, varscan2
- MAML3 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 19/363 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV59077871; called by muse, mutect2
- MAOA | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs140295792, COSV58641530; called by muse, mutect2, varscan2
- MGAM | c.4513G>T p.G1505W | Missense Mutation (SNP) | VAF 12/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074484; called by muse, mutect2
- MMP13 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1030769829; called by muse, varscan2
- MORC1 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV51717090; called by muse, mutect2, varscan2
- MPI | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1237538373, COSV100086297; called by muse, mutect2, varscan2
- MSRB1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs565623090, COSV51905552; called by muse, mutect2, varscan2
- MUC15 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs267602834, COSV55557730; called by muse, mutect2
- MUC16 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs752724664, COSV67458170; called by muse, mutect2, varscan2
- MUC17 | c.9077C>T p.S3026F | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as rs1220192316, COSV60305379; called by muse, mutect2, varscan2
- MUC4 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.934); catalogued as rs1560402606, COSV62150038; called by muse, mutect2
- MYH15 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1323114620; called by muse, mutect2, varscan2
- MYH7B | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52683152; called by muse, mutect2, varscan2
- MYLK2 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 81/519 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs6060969, COSV65659031; called by muse, mutect2, varscan2
- MYO18B | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1251334068; called by muse, mutect2
- MYO18B | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 54/443 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746828963, COSV100122452; called by muse, mutect2, varscan2
- MYO1A | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354540592, COSV55655660; called by muse, mutect2
- NCAPG2 | c.3211G>C p.A1071P | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV51987693; called by muse, mutect2
- NCF4 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs371008750; called by muse, mutect2, varscan2
- NEB | c.6524G>A p.W2175* | Nonsense Mutation (SNP) | VAF 33/352 reads (9%) | catalogued as COSV99427861; called by muse, mutect2
- NEXMIF | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50021492; called by muse, mutect2, varscan2
- NLGN1 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64323869, COSV64337003; called by muse, mutect2, varscan2
- NLRP11 | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs374728544; called by muse, mutect2, varscan2
- NLRP3 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs757698137, COSV60222781; called by muse, mutect2
- NLRP4 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 82/461 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.047); catalogued as COSV56723016; called by muse, mutect2
- NLRP5 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs368914781, COSV66762342; called by muse, mutect2, varscan2
- NLRP7 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 63/539 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1250667222, COSV60171770, COSV60182377; called by muse, mutect2, varscan2
- NLRP8 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs866751626, COSV99405586; called by muse, mutect2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2
- NPY4R | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 31/1193 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs782024830, COSV65398029; called by muse, mutect2
- NUP210 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1380145119, COSV54408879; called by muse, mutect2
- OGDHL | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1371950699; called by muse, mutect2
- OLFML3 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57436990; called by muse, mutect2, varscan2
- OPRM1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1010052797, COSV100001511, COSV57674181; called by muse, mutect2, varscan2
- OR13A1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs550506080; called by muse, mutect2, varscan2
- OR1L1 | c.244C>T p.L82F (on ENST00000373686; = p.L32F on NM_001005236.3) | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1258905587; called by muse, mutect2
- OR4B1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs150005719, COSV58882318; called by muse, mutect2
- OR4E1 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs544806162; called by muse, mutect2, varscan2
- OR4K2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53847918, COSV53848106; called by muse, mutect2, varscan2
- OR4L1 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 29/199 reads (15%) | catalogued as rs757998914; called by muse, mutect2, varscan2
- OR51B4 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1439027031; called by muse, mutect2, varscan2
- OR51E1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV67809520, COSV67810482; called by muse, mutect2, varscan2
- OR52E6 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV61432757; called by muse, mutect2
- OR5G3 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs1565088000; called by muse, mutect2, varscan2
- OR5M1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435320828; called by muse, mutect2, varscan2
- OR6K6 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs779056999, COSV63744109; called by muse, mutect2
- OR8B3 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV63541513; called by muse, mutect2, varscan2
- OR8S1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV59599512; called by muse, mutect2, varscan2
- OTOG | c.5018C>T p.S1673L | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1475473043; called by muse, mutect2
- OTOGL | c.6998G>A p.G2333E (on ENST00000547103; = p.G2324E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1260290150, COSV54018199; called by muse, mutect2
- OTULIN | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375220163; called by muse, mutect2
- PABPC1L | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 42/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV53842131; called by muse, mutect2
- PAK5 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV62026134; called by muse, mutect2, varscan2
- PAPOLB | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs748882070, COSV68200554; called by muse, mutect2
- PAPPA | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs868292130, COSV60292745; called by muse, mutect2, varscan2
- PAPPA2 | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as COSV62801425; called by muse, mutect2
- PCARE | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 94/486 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs554397247; called by muse, mutect2, varscan2
- PCDH9 | c.3250C>T p.L1084F (on ENST00000377865 / NM_203487.3; = p.L1050F on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60525097; called by muse, mutect2
- PCDHA3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 83/643 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63541065; called by muse, mutect2, varscan2
- PCDHA5 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 57/406 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV65350652; called by muse, mutect2, varscan2
- PCDHB6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV50691822; called by muse, mutect2, varscan2
- PCDHGA9 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 65/452 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs749341214; called by muse, mutect2, varscan2
- PCDHGB4 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749167212; called by muse, mutect2
- PCDHGB5 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as COSV53931319; called by muse, mutect2, varscan2
- PCLO | c.10219G>A p.E3407K | Missense Mutation (SNP) | VAF 45/415 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1282303356, COSV61621336; called by muse, mutect2, varscan2
- PCLO | c.7946C>T p.S2649F | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV61639050; called by muse, mutect2, varscan2
- PCLO | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777818111, COSV61617400; called by muse, mutect2, varscan2
- PCNX3 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.981); catalogued as rs1046512384; called by muse, mutect2, varscan2
- PDE1B | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs557008061, COSV54494246; called by muse, mutect2, varscan2
- PDE8B | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99366266; called by muse, mutect2, varscan2
- PGGHG | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 44/537 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs978246689, COSV101164398; called by muse, mutect2
- PHF21A | c.1982C>T p.A661V (on ENST00000418153 / NM_001101802.3; = p.A615V on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/543 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.061); catalogued as rs1063810; called by muse, mutect2, varscan2
- PID1 | c.568G>A p.D190N (on ENST00000354069 / NM_001330156.1; = p.D188N on NM_017933.5) | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as rs778222068; called by muse, mutect2
- PIGO | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1220682305, COSV53055595; called by muse, mutect2, varscan2
- PIK3CB | c.1461T>G p.N487K | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV56687638; called by muse, mutect2, varscan2
- PIWIL2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.013); catalogued as COSV63252681; called by muse, mutect2, varscan2
- PKHD1L1 | c.11791G>A p.E3931K | Missense Mutation (SNP) | VAF 52/422 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV65749561; called by muse, mutect2, varscan2
- PLPPR3 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs928637718; called by muse, mutect2, varscan2
- PLXNA3 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV63756114; called by muse, mutect2, varscan2
- POLE2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs767851728; called by muse, mutect2, varscan2
- POU6F2 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs202234462, COSV101302642; called by muse, mutect2, varscan2
- PPFIA2 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1296624902, COSV61045372; called by muse, mutect2
- PPP3R2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1472868875, COSV100701373; called by muse, mutect2, varscan2
- PRDM9 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as rs570195744; called by muse, mutect2, varscan2
- PRKAG2 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55235773; called by muse, mutect2, varscan2
- PRNP | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs770422749, COSV99058565; called by muse, mutect2, varscan2
- PRPS1L1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 54/398 reads (14%) | catalogued as COSV72649856; called by muse, mutect2, varscan2
- PSMF1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 70/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375788504; called by muse, mutect2, varscan2
- PTPRD | c.5687C>T p.S1896F | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV61938102; called by muse, mutect2
- PTPRD | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV61931708; called by muse, mutect2, varscan2
- RBM47 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV55942440; called by mutect2, varscan2
- RBMXL3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.097); catalogued as rs1363399345; called by muse, mutect2, varscan2
- RD3L | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1409806392; called by muse, mutect2, varscan2
- RGS7 | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs765416370; called by muse, mutect2
- RGS7BP | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV61834555, COSV61835975; called by muse, mutect2, varscan2
- RIMBP2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs755282733; called by muse, mutect2, varscan2
- RIT2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267605184, COSV56300970; called by muse, mutect2
- RPN1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749479360, COSV99956849; called by muse, mutect2
- SACS | c.7394C>T p.S2465L | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs747676277, COSV66533758; called by muse, mutect2
- SACS | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV66544867; called by muse, mutect2
- SCIN | c.1703A>G p.Y568C (on ENST00000297029 / NM_001112706.3; = p.Y321C on NM_033128.3) | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs750117695; called by muse, mutect2, varscan2
- SCN1A | c.3884C>T p.S1295L (on ENST00000303395 / NM_001202435.3; = p.S1284L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57682165; called by muse, mutect2, varscan2
- SCN2A | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV51836882; called by muse, mutect2, varscan2
- SCYL1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as rs754208663; called by muse, mutect2, varscan2
- SDR16C5 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58126866; called by muse, varscan2
- SERPINB3 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV52190211; called by muse, mutect2
- SEZ6L | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as rs781334572, COSV50664394; called by muse, mutect2, varscan2
- SH3GL3 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs142360966; called by muse, mutect2, varscan2
- SHANK2 | c.5086G>A p.D1696N | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs781858199; called by muse, mutect2, varscan2
- SHISA9 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs770339542; called by muse, mutect2
- SIGIRR | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1404103800; called by muse, mutect2, varscan2
- SIRPB1 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV53539657; called by muse, mutect2, varscan2
- SIRT7 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs780396449, COSV58710963; called by muse, mutect2, varscan2
- SLC26A7 | c.1098G>C p.M366I | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99404497; called by muse, mutect2, varscan2
- SLC36A1 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 43/447 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs775913829; called by muse, mutect2, varscan2
- SLC4A4 | c.1150G>A p.E384K (on ENST00000264485 / NM_001098484.3; = p.E340K on NM_003759.4) | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV52619619; called by muse, mutect2
- SLC5A8 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 39/284 reads (14%) | catalogued as rs774392367, COSV73310408; called by muse, mutect2, varscan2
- SLC6A13 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100570014; called by muse, mutect2
- SLITRK4 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62025069; called by muse, mutect2, varscan2
- SNTG2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774232298, COSV58000773; called by muse, mutect2
- SPATA16 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | catalogued as rs745984261; called by muse, mutect2
- SPATA31E1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.162); catalogued as rs754686978, COSV57790205; called by muse, mutect2, varscan2
- SPATA9 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV57224205; called by muse, mutect2, varscan2
- SRPK2 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs892487360; called by muse, mutect2, varscan2
- STON1 | c.1734G>A p.W578* | Nonsense Mutation (SNP) | VAF 26/466 reads (6%) | catalogued as rs1170091939; called by muse, mutect2
- SYMPK | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55612065; called by muse, mutect2, varscan2
- TAFA5 | c.310G>A p.E104K (on ENST00000402357 / NM_001082967.3; = p.E97K on NM_015381.7) | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV60972448; called by muse, mutect2, varscan2
- TBX10 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs1330568058; called by muse, mutect2
- TG | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 43/546 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.406); catalogued as rs753308520, COSV55071126; called by muse, mutect2
- TGIF2LX | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV52213087; called by muse, mutect2, varscan2
- THSD7B | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753986556; called by muse, mutect2, varscan2
- TINAG | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514623; called by muse, mutect2, varscan2
- TJAP1 | c.734A>G p.N245S (on ENST00000372445 / NM_001146016.1; = p.N235S on NM_080604.3) | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV52501911; called by muse, mutect2, varscan2
- TJP3 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 60/420 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV53663460; called by muse, mutect2, varscan2
- TLE1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV64689275; called by muse, mutect2
- TM6SF1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99362510; called by muse, mutect2
- TMEM17 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273437469; called by muse, mutect2
- TMEM253 | c.501G>T p.R167S | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV62878688; called by muse, mutect2
- TMPO | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs767091554; called by muse, mutect2, varscan2
- TNFRSF10C | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as rs867204990; called by muse, mutect2
- TNIP3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs764235001, COSV50246018, COSV99284504; called by muse, mutect2, varscan2
- TOGARAM1 | c.4148G>A p.G1383E | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100817976; called by muse, mutect2, varscan2
- TRAPPC9 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs780990607, COSV66910018; called by mutect2, varscan2
- TRIO | c.5710C>T p.P1904S | Missense Mutation (SNP) | VAF 110/417 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60084243; called by muse, varscan2
- TRIO | c.5711C>A p.P1904Q | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60084075; called by muse, mutect2, varscan2
- TRPV1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 64/478 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1197245682; called by muse, mutect2, varscan2
- UBC | c.1953G>T p.L651F | Missense Mutation (SNP) | VAF 30/531 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV60061184; called by muse, mutect2
- UBR1 | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771728220; called by muse, mutect2, varscan2
- UBR4 | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as rs776593168, COSV64391881, COSV64395742; called by muse, mutect2, varscan2
- UBXN10 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs1301217143; called by muse, mutect2, varscan2
- UGT2A1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99684859; called by muse, mutect2
- UGT2B15 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV57733144; called by muse, mutect2
- VTN | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782168976, COSV56873761; called by muse, mutect2
- WBP1L | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1434466082; called by muse, mutect2
- WDR36 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV72605043; called by muse, mutect2, varscan2
- WFDC8 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 44/338 reads (13%) | catalogued as rs1336540586; called by muse, mutect2, varscan2
- WNT7A | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs917713880, COSV53199892; called by muse, mutect2
- ZC3H12D | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs999903222; called by muse, mutect2, varscan2
- ZDBF2 | c.2585G>A p.R862K | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs749384963, COSV65624943; called by muse, mutect2
- ZFPM2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1376787277; called by muse, mutect2, varscan2
- ZNF208 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs375447085, COSV68099457; called by muse, mutect2
- ZNF44 | c.1318C>T p.P440S (on ENST00000356109 / NM_001164276.2; = p.P392S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759680088, COSV61135294; called by muse, mutect2, varscan2
- ZNF804A | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV56447252; called by muse, mutect2, varscan2
- ZNF831 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV64041262; called by muse, mutect2, varscan2
- ZNF837 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774083994; called by muse, mutect2
- ABCC3 | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- AC011005.1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 59/431 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ACP3 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ACRBP | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACSM5 | c.1141A>C p.N381H | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.445); called by muse, mutect2
- ADAM28 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAM9 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY7 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRB3 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMER3 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- ANK3 | c.7084C>T p.Q2362* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- ANKIB1 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.3785G>A p.S1262N (on ENST00000611781; = p.S1206N on NM_052997.2) | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ASTN1 | c.3508G>T p.G1170W | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ATP1A2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BAHCC1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 83/548 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- BCS1L | c.1022T>A p.L341Q | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMI1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 67/389 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BNIP5 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 69/506 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BRINP1 | c.1140A>T p.R380S | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.879); called by muse, mutect2
- C1QTNF3 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- C2CD4C | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2orf16 | c.96T>A p.F32L | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- C6 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CACNA1F | c.5299C>G p.P1767A | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAVIN1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CCDC127 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 146/474 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by mutect2, varscan2
- CCDC83 | c.333A>C p.K111N | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2
- CCDC91 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC42BPA | c.1496T>A p.L499Q | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDC45 | c.520C>G p.R174G | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CEACAM1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CELSR2 | c.5620T>A p.C1874S | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CERKL | c.1669C>T p.P557S (on ENST00000339098 / NM_001030311.2; = p.P531S on NM_201548.5) | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- CES5A | c.707T>G p.I236R | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CFHR3 | c.298del p.Y100Mfs*52 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | called by mutect2, pindel, varscan2
- CHSY3 | c.2388T>G p.F796L | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CLSPN | c.2390C>A p.T797N | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CNOT1 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- CNR1 | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- COL6A5 | c.4516G>A p.G1506R | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CP | c.593T>A p.I198K | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CREB1 | c.405G>A p.R135= (on ENST00000432329 / NM_134442.5; = p.R121= on NM_004379.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- CRYBG1 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CTNND2 | c.3507G>C p.E1169D | Missense Mutation (SNP) | VAF 53/653 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CXCR5 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CYP1A2 | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CYP2C18 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- DCAF8L1 | c.722A>T p.N241I | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX3X | c.151_154delinsCG p.F51Rfs*3 (on ENST00000399959; = p.F52Rfs*3 on NM_001356.5) | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | called by pindel, varscan2*
- DENND11 | c.787T>G p.S263A | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DIAPH1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIP2C | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DLEC1 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- DMTN | c.781T>A p.L261M | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DOCK3 | c.3929G>A p.G1310E | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DSCAM | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSCAML1 | c.6253G>A p.D2085N (on ENST00000321322; = p.D2025N on NM_020693.4) | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DSG4 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- DYNC1I2 | c.1046_1048del p.V349del | In Frame Del (DEL) | VAF 44/263 reads (17%) | called by pindel, varscan2
- EBF2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EEF1A2 | c.310A>C p.T104P | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- EFCAB6 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 47/393 reads (12%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.2368G>A p.V790I (on ENST00000450689 / NM_001142749.3; = p.V623I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELOA2 | c.1520G>A p.R507K | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- EMILIN2 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.035); called by muse, mutect2
- EPB41L4B | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA6 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 33/404 reads (8%) | called by muse, mutect2
- EXPH5 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- FAM120C | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FAM184B | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FAM214B | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM83B | c.1895C>T p.T632I | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM83B | c.2936T>C p.L979P | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- FAT3 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FETUB | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FHL5 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLAD1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLT4 | c.4038G>T p.E1346D | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FPR1 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FREM1 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FREM3 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2
- FSTL5 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.837); called by muse, mutect2
- G3BP1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GABPA | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GAGE2E | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 30/759 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2
- GDI2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GIPC3 | c.3763C>T p.Q1255* | Nonsense Mutation (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- GOLGA5 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH8 | c.934_936delinsTT p.E313Nfs*3 | Frame Shift Del (DEL) | VAF 61/486 reads (13%) | called by pindel, varscan2*
- GRB10 | c.1636C>T p.P546S (on ENST00000398812; = p.P500S on NM_001001549.3) | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2
- GRID2IP | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2
- GYS2 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HAPLN2 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HASPIN | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- HCN1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HECA | c.1468-1G>A p.X490_splice | Splice Site (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- HELZ2 | c.2759C>T p.S920F (on ENST00000467148 / NM_001037335.2; = p.S351F on NM_033405.3) | Missense Mutation (SNP) | VAF 68/500 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HELZ2 | c.1943C>T p.T648I (on ENST00000467148 / NM_001037335.2; = p.T79I on NM_033405.3) | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HIP1 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLA-DOB | c.179T>G p.L60W | Missense Mutation (SNP) | VAF 63/606 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HMCN2 | c.13867G>A p.G4623R | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HSPA4L | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGLV5-37 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- IGSF10 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 42/505 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL25 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 53/486 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ISOC2 | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- ITIH1 | c.2269T>A p.F757I | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- KIAA1549L | c.4315G>T p.A1439S (on ENST00000321505; = p.A1736S on NM_012194.3) | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by mutect2, varscan2
- KIF18B | c.1076T>G p.V359G | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- KIF2B | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- KIR3DL3 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLB | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KLHL4 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- L1TD1 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- LAMB2 | c.4787G>C p.W1596S | Missense Mutation (SNP) | VAF 29/369 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- LARGE2 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- LCN6 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- LCP2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LINC02218 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 212/534 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LINGO4 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 55/456 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LINS1 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 28/291 reads (10%) | called by muse, mutect2
- LRP1B | c.6704G>A p.R2235K | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.4243A>T p.K1415* | Nonsense Mutation (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- LRRC4B | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- LRRC4C | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRD1 | c.1643T>C p.I548T | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LRRN4 | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LVRN | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LY75 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MACROD2 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MAGEC3 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MALRD1 | c.3644G>A p.W1215* | Nonsense Mutation (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- MAN2C1 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MAP7D2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MB21D2 | c.1430A>T p.D477V | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MBD4 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- MEF2D | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- MEGF8 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MEGF8 | c.3805C>T p.L1269F (on ENST00000251268 / NM_001271938.2; = p.L1202F on NM_001410.3) | Missense Mutation (SNP) | VAF 56/419 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MGAM2 | c.4925G>A p.G1642E | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MKRN3 | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLPH | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 79/422 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MLX | c.558T>A p.F186L | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2
- MLXIP | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 60/499 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMP11 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MON1A | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRC1 | c.3343C>T p.Q1115* | Nonsense Mutation (SNP) | VAF 83/442 reads (19%) | called by muse, mutect2, varscan2
- MROH2A | c.2965C>T p.H989Y | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2
- MS4A6E | c.147G>A p.G49= | Splice Region (SNP) | VAF 25/211 reads (12%) | called by muse, mutect2, varscan2
- MTMR3 | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); called by muse, mutect2
- MUC16 | c.21860G>A p.S7287N | Missense Mutation (SNP) | VAF 31/361 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.352); called by muse, mutect2
- MUC16 | c.21358T>G p.S7120A | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.14371G>A p.D4791N | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MUC16 | c.10600C>T p.P3534S | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- MUC16 | c.7149G>A p.M2383I | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); called by muse, mutect2
- MYBL1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH13 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- MYH7 | c.5411C>T p.A1804V | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDNF | c.407T>C p.F136S | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); called by muse, mutect2
- NEO1 | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 50/257 reads (19%) | called by muse, mutect2, varscan2
- NES | c.2845C>T p.Q949* | Nonsense Mutation (SNP) | VAF 37/450 reads (8%) | called by muse, mutect2
- NLRP3 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- NLRP4 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NOTCH3 | c.6428C>T p.P2143L | Missense Mutation (SNP) | VAF 84/604 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- NOTCH4 | c.3413C>T p.S1138F | Missense Mutation (SNP) | VAF 77/652 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NR5A2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2
- NUP210L | c.2554+1G>A p.X852_splice | Splice Site (SNP) | VAF 41/257 reads (16%) | called by muse, mutect2, varscan2
- NUP210L | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NWD1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- OBSCN | c.6872C>A p.T2291N | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.258); called by muse, mutect2
- OGFR | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 61/560 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR10G4 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR10K1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10Z1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14C36 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR4D9 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 23/418 reads (6%) | called by muse, mutect2
- OR51F2 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52B2 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6C4 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR7G2 | c.914T>G p.M305R | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- OSBPL5 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- PCDHB15 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PCLAF | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCLO | c.12054A>C p.R4018S | Missense Mutation (SNP) | VAF 42/437 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCLO | c.4106G>A p.G1369E | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCNX3 | c.1969A>C p.T657P | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDE11A | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PDE4DIP | c.2375T>G p.V792G | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PGK2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2
- PHLDB2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PIAS3 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PKD2 | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- PKHD1L1 | c.3328C>T p.L1110F | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PLCB1 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLD1 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEC | c.13520C>T p.A4507V (on ENST00000322810 / NM_201380.4; = p.A4397V on NM_000445.5) | Missense Mutation (SNP) | VAF 54/510 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.049); called by muse, varscan2
- PLEKHA7 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMS1 | c.929T>C p.L310S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- POC5 | c.749G>A p.R250K (on ENST00000428202 / NM_001099271.2; = p.R225K on NM_152408.2) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- POU5F1 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 74/504 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- PPP1R13L | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PPP1R32 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PQBP1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PREX2 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PROX2 | c.1440G>A p.M480I (on ENST00000556489 / NM_001243007.1; = p.M253I on NM_001080408.2) | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PTAR1 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2
- PTTG2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2
- RAG1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RANBP3 | c.1178C>T p.T393I (on ENST00000340578 / NM_007322.3; = p.T388I on NM_003624.3) | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- RAP1GDS1 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- RAPGEF5 | c.1529G>A p.G510E (on ENST00000401957 / NM_001367602.2; = p.G813E on NM_012294.5) | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAPGEF6 | c.1952A>G p.D651G | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2
- RBL2 | c.3206C>A p.P1069H | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM47 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by mutect2, varscan2
- REC114 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- REEP1 | c.303+1G>A p.X101_splice | Splice Site (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2
- RESF1 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- REST | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- RNF165 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RNF165 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- RPAP1 | c.1492C>T p.Q498* | Nonsense Mutation (SNP) | VAF 26/353 reads (7%) | called by muse, mutect2
- RPS6KA6 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTL4 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RYR3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD4B | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCN10A | c.5395C>T p.H1799Y | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SCN7A | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- SELE | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SENP6 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SHISA7 | c.465_466delinsA p.P157Qfs*74 | Frame Shift Del (DEL) | VAF 39/302 reads (13%) | called by pindel, varscan2*
- SKP2 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 129/472 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC10A5 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC12A5 | c.298G>A p.E100K (on ENST00000454036 / NM_001134771.2; = p.E77K on NM_020708.5) | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SLC17A6 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC22A6 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC28A2 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35A4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC45A4 | c.533C>T p.P178L (on ENST00000517878 / NM_001286646.2; = p.P127L on NM_001080431.2) | Missense Mutation (SNP) | VAF 55/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A10 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.2181G>A p.W727* | Nonsense Mutation (SNP) | VAF 55/420 reads (13%) | called by muse, mutect2, varscan2
- SLX4 | c.4297C>T p.L1433F | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- SMCHD1 | c.5134C>T p.L1712F | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- SMG6 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMIM40 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 64/388 reads (16%) | called by muse, mutect2, varscan2
- SP2 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SPACA7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- SPANXN4 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STAG3 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SUCNR1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2
- SULT1A2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 50/463 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.105); called by muse, varscan2
- SVOPL | c.543G>A p.W181* (on ENST00000419765; = p.W29* on NM_174959.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/261 reads (10%) | called by muse, mutect2, varscan2
- SYNE2 | c.19731A>T p.L6577F | Missense Mutation (SNP) | VAF 46/475 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYT16 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 81/497 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SYT16 | c.1543T>A p.Y515N | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAP1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 91/626 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TCF20 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 70/582 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TDRD15 | c.4975G>A p.D1659N | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT4B | c.2075A>G p.N692S (on ENST00000561678 / NM_001365323.2; = p.N677S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TESK1 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 51/542 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TEX14 | c.4285G>A p.G1429S (on ENST00000240361 / NM_001201457.2; = p.G1383S on NM_031272.5) | Missense Mutation (SNP) | VAF 21/319 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- TEX38 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, varscan2
- TGM4 | c.1074G>A p.Q358= | Splice Region (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- THADA | c.5854G>A p.A1952T | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- THSD4 | c.1907-1G>A p.X636_splice | Splice Site (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- TMEM19 | c.850T>C p.L284= | Splice Region (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- TMEM248 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TMEM253 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TMPRSS4 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TMPRSS5 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TPO | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2
- TPTE | c.444A>T p.E148D (on ENST00000618007 / NM_199261.4; = p.E130D on NM_199259.4) | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2
- TRAPPC6A | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRAPPC9 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 56/410 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRAV5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, varscan2
- TRAV8-4 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 73/375 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRBV7-1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, varscan2
- TRIM46 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, varscan2
- TRPM5 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSR1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- TTN | c.18870G>A p.W6290* (on ENST00000591111; = p.W5363* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- UBB | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, varscan2
- UBB | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.156); called by muse, varscan2
- UBE2O | c.1950_1951insA p.F651Ifs*2 | Frame Shift Ins (INS) | VAF 34/304 reads (11%) | called by mutect2, pindel, varscan2
- USF3 | c.4609T>C p.S1537P | Missense Mutation (SNP) | VAF 76/367 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- USH2A | c.13994G>A p.G4665E | Missense Mutation (SNP) | VAF 43/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.12565G>A p.E4189K | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- VPS54 | c.1898T>A p.M633K | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- VWA5B1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA8 | c.4405C>T p.P1469S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- VWDE | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- VWDE | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- XIRP2 | c.5098C>T p.L1700F (on ENST00000628543; = p.L1875F on NM_152381.6) | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- XKR3 | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- XKR7 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED9 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB14 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- ZBTB34 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFAT | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF134 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF134 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF331 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF45 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF585B | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 58/484 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF683 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZNF711 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF879 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF99 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZSCAN10 | c.893G>A p.G298E (on ENST00000252463; = p.G353E on NM_032805.3) | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSCAN5B | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC9 | c.1938G>A p.Q646= | Silent (SNP) | VAF 35/360 reads (10%) | catalogued as rs755853969, COSV53985016; called by muse, mutect2
- AC013489.1 | c.1476G>A p.R492= | Silent (SNP) | VAF 30/367 reads (8%) | called by muse, mutect2
- ACACB | c.4680C>T p.Y1560= | Silent (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- ACOX2 | c.981G>A p.R327= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV57149868; called by muse, mutect2
- ACTC1 | c.27C>T p.A9= | Silent (SNP) | VAF 31/389 reads (8%) | called by muse, mutect2
- ACY3 | c.591C>T p.T197= | Silent (SNP) | VAF 46/361 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.1908C>T p.S636= | Silent (SNP) | VAF 56/406 reads (14%) | catalogued as rs1422057279; called by muse, mutect2, varscan2
- ADAMTS14 | c.342G>A p.G114= | Silent (SNP) | VAF 28/429 reads (7%) | catalogued as COSV100941573; called by muse, mutect2
- ADAMTS2 | c.3384A>G p.V1128= | Silent (SNP) | VAF 14/512 reads (3%) | called by muse, mutect2
- ADCY6 | c.987C>T p.L329= | Silent (SNP) | VAF 23/348 reads (7%) | called by muse, mutect2
- ADGRL3 | c.2139C>T p.L713= (on ENST00000506720 / NM_001322402.2; = p.L645= on NM_015236.6) | Silent (SNP) | VAF 39/293 reads (13%) | called by muse, mutect2, varscan2
- ADH1B | c.810C>T p.I270= | Silent (SNP) | VAF 47/317 reads (15%) | catalogued as rs904388509; called by muse, mutect2, varscan2
- AKNA | c.4170C>T p.L1390= | Silent (SNP) | VAF 77/556 reads (14%) | catalogued as rs1363804067; called by muse, mutect2, varscan2
- AL358113.1 | c.3888C>T p.R1296= | Silent (SNP) | VAF 30/426 reads (7%) | called by muse, mutect2
- ALKBH4 | c.888C>T p.S296= | Silent (SNP) | VAF 34/270 reads (13%) | catalogued as COSV52961824; called by muse, mutect2, varscan2
- ANGEL1 | c.1887C>T p.L629= | Silent (SNP) | VAF 43/284 reads (15%) | called by muse, mutect2, varscan2
- ANK3 | c.4689C>T p.S1563= | Silent (SNP) | VAF 30/418 reads (7%) | called by muse, mutect2
- ANKIB1 | c.2610C>T p.A870= | Silent (SNP) | VAF 42/324 reads (13%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3453G>A p.E1151= | Silent (SNP) | VAF 44/441 reads (10%) | called by muse, mutect2, varscan2
- ANKRD30A | c.999G>A p.E333= (on ENST00000611781; = p.E277= on NM_052997.2) | Silent (SNP) | VAF 56/447 reads (13%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3108G>A p.E1036= (on ENST00000611781; = p.E980= on NM_052997.2) | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- ANKZF1 | c.940C>T p.L314= | Silent (SNP) | VAF 26/454 reads (6%) | called by muse, mutect2
- ANO4 | c.1326G>A p.L442= (on ENST00000392977 / NM_001286615.2; = p.L407= on NM_178826.4) | Silent (SNP) | VAF 32/372 reads (9%) | called by muse, mutect2
- ANPEP | c.381C>T p.L127= | Silent (SNP) | VAF 32/478 reads (7%) | catalogued as COSV55592757; called by muse, mutect2
- AP4M1 | c.337C>T p.L113= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- APOBEC3G | c.492C>T p.F164= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as rs143077923, COSV68470136; called by muse, mutect2
- ARHGAP28 | c.846G>A p.E282= (on ENST00000383472 / NM_001366230.1; = p.E123= on NM_001010000.3) | Silent (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
- ARHGAP30 | c.1632G>A p.G544= | Silent (SNP) | VAF 68/477 reads (14%) | catalogued as rs1429262782; called by muse, mutect2, varscan2
- ARHGEF17 | c.1194C>T p.T398= | Silent (SNP) | VAF 47/367 reads (13%) | catalogued as rs770366199; called by muse, mutect2, varscan2
- ASB15 | c.1300C>T p.L434= | Silent (SNP) | VAF 41/306 reads (13%) | called by muse, mutect2, varscan2
- ASS1 | c.294C>T p.I98= | Silent (SNP) | VAF 47/385 reads (12%) | catalogued as rs183370361, COSV61690167; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASXL1 | c.970C>T p.L324= | Silent (SNP) | VAF 77/314 reads (25%) | called by muse, mutect2, varscan2
- ATF6 | c.585C>T p.N195= | Silent (SNP) | VAF 44/402 reads (11%) | called by muse, mutect2, varscan2
- ATF6B | c.456C>T p.I152= | Silent (SNP) | VAF 32/287 reads (11%) | catalogued as rs1333036530; called by muse, mutect2, varscan2
- ATP10B | c.1575G>A p.G525= | Silent (SNP) | VAF 44/404 reads (11%) | catalogued as rs1403459111; called by muse, mutect2, varscan2
- ATP2B3 | c.1746C>T p.S582= | Silent (SNP) | VAF 36/149 reads (24%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3486C>T p.V1162= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs782815173, COSV100370132; called by muse, mutect2, varscan2
- BAHCC1 | c.7350C>G p.A2450= | Silent (SNP) | VAF 53/390 reads (14%) | catalogued as COSV57030972; called by muse, mutect2, varscan2
- BOD1L2 | c.117C>T p.I39= | Silent (SNP) | VAF 32/376 reads (9%) | catalogued as rs765631800; called by muse, mutect2
- C16orf72 | c.147C>T p.A49= | Silent (SNP) | VAF 66/396 reads (17%) | called by muse, mutect2, varscan2
- C1orf198 | c.54G>A p.G18= | Silent (SNP) | VAF 37/410 reads (9%) | catalogued as rs1008287840; called by muse, mutect2
- C6 | c.2058C>T p.C686= | Silent (SNP) | VAF 26/466 reads (6%) | catalogued as COSV99667315; called by muse, mutect2
- C6 | c.204G>A p.Q68= | Silent (SNP) | VAF 43/413 reads (10%) | called by muse, mutect2, varscan2
- CACNA1B | c.6921C>T p.L2307= | Silent (SNP) | VAF 66/463 reads (14%) | called by muse, mutect2, varscan2
- CADM2 | c.855C>T p.F285= (on ENST00000407528 / NM_001167674.2; = p.F287= on NM_153184.4) | Silent (SNP) | VAF 53/373 reads (14%) | catalogued as COSV67376010; called by muse, mutect2, varscan2
- CAMTA2 | c.2850A>T p.T950= | Silent (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- CASR | c.480C>T p.F160= | Silent (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- CAV3 | c.255C>T p.A85= | Silent (SNP) | VAF 26/351 reads (7%) | catalogued as rs1400119189; called by muse, mutect2
- CAVIN2 | c.546G>A p.G182= | Silent (SNP) | VAF 69/370 reads (19%) | catalogued as COSV58425898; called by muse, mutect2, varscan2
- CCDC168 | c.20124C>T p.S6708= | Silent (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- CCDC175 | c.867G>A p.E289= | Silent (SNP) | VAF 41/276 reads (15%) | called by muse, mutect2, varscan2
- CCDC188 | c.333G>A p.S111= | Silent (SNP) | VAF 71/554 reads (13%) | catalogued as rs1040331494; called by muse, mutect2, varscan2
- CCDC87 | c.2400C>T p.F800= | Silent (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- CCHCR1 | c.1053G>A p.Q351= | Silent (SNP) | VAF 60/454 reads (13%) | catalogued as COSV100885634; called by muse, mutect2, varscan2
- CCNB3 | c.3066G>A p.G1022= | Silent (SNP) | VAF 53/242 reads (22%) | catalogued as COSV99329534; called by muse, mutect2, varscan2
- CCNE2 | c.1107A>G p.E369= | Silent (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2
- CCNF | c.2295G>A p.V765= | Silent (SNP) | VAF 45/355 reads (13%) | catalogued as rs1048325887, COSV53540029; called by muse, mutect2, varscan2
- CD6 | c.1611C>T p.I537= | Silent (SNP) | VAF 24/415 reads (6%) | called by muse, mutect2
- CDRT1 | c.1809G>A p.G603= | Silent (SNP) | VAF 40/482 reads (8%) | called by muse, mutect2
- CEP120 | c.2250A>G p.E750= | Silent (SNP) | VAF 42/434 reads (10%) | called by muse, mutect2
- CEP162 | c.1803C>T p.S601= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- CFAP126 | c.411A>G p.Q137= | Silent (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- CFAP36 | c.474G>A p.R158= | Silent (SNP) | VAF 55/256 reads (21%) | called by muse, mutect2, varscan2
- CFAP46 | c.6288G>A p.T2096= | Silent (SNP) | VAF 28/315 reads (9%) | catalogued as rs767135035; called by muse, mutect2
- CFAP54 | c.7950G>A p.L2650= | Silent (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- CHAF1B | c.1377C>T p.P459= | Silent (SNP) | VAF 65/473 reads (14%) | called by muse, mutect2, varscan2
- CIR1 | c.354C>T p.P118= | Silent (SNP) | VAF 46/240 reads (19%) | catalogued as rs768741194, COSV100565128; called by muse, mutect2, varscan2
- CLIC6 | c.1125G>A p.E375= | Silent (SNP) | VAF 48/441 reads (11%) | catalogued as rs1169756697; called by muse, mutect2, varscan2
- CLIC6 | c.1884G>A p.R628= (on ENST00000360731 / NM_001317009.2; = p.R610= on NM_053277.3) | Silent (SNP) | VAF 60/429 reads (14%) | catalogued as COSV62448929; called by muse, mutect2, varscan2
- CLIP2 | c.2604C>T p.D868= | Silent (SNP) | VAF 41/373 reads (11%) | catalogued as rs542790637, COSV99792187; called by muse, mutect2
- CLVS2 | c.651C>T p.F217= | Silent (SNP) | VAF 33/223 reads (15%) | catalogued as COSV51562848; called by muse, mutect2, varscan2
- CNKSR3 | c.1482C>T p.V494= | Silent (SNP) | VAF 51/373 reads (14%) | called by muse, mutect2, varscan2
- COBL | c.1026G>A p.Q342= | Silent (SNP) | VAF 45/331 reads (14%) | catalogued as rs569458434; called by muse, mutect2, varscan2
- COL15A1 | c.3021G>A p.Q1007= | Silent (SNP) | VAF 16/387 reads (4%) | called by muse, mutect2
- COL1A1 | c.1419T>C p.G473= | Silent (SNP) | VAF 49/372 reads (13%) | called by muse, mutect2, varscan2
- COL5A3 | c.2205C>T p.F735= | Silent (SNP) | VAF 43/357 reads (12%) | catalogued as rs764220031, COSV53414324; called by muse, mutect2, varscan2
- CPT1C | c.1230G>A p.G410= | Silent (SNP) | VAF 42/482 reads (9%) | catalogued as rs1399204590; called by muse, mutect2
- CPXCR1 | c.216C>T p.L72= | Silent (SNP) | VAF 61/244 reads (25%) | catalogued as COSV52161792; called by muse, mutect2, varscan2
- CROCC2 | c.3648C>T p.A1216= | Silent (SNP) | VAF 62/303 reads (20%) | catalogued as rs1197471628; called by muse, mutect2, varscan2
- CSF2RA | c.717G>A p.Q239= | Silent (SNP) | VAF 54/507 reads (11%) | called by muse, mutect2, varscan2
- CSMD2 | c.1806C>T p.L602= | Silent (SNP) | VAF 77/353 reads (22%) | called by muse, mutect2, varscan2
- CTPS1 | c.480T>C p.I160= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as rs761028193; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCDC1 | c.5268C>T p.I1756= (on ENST00000597505 / NM_001367979.1; = p.I863= on NM_020869.3) | Silent (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2, varscan2
- DCLRE1B | c.417C>T p.I139= | Silent (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- DEPDC1 | c.1206T>C p.N402= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2, varscan2
- DGKE | c.1293G>A p.L431= | Silent (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2, varscan2
- DLEC1 | c.2235C>T p.I745= | Silent (SNP) | VAF 17/392 reads (4%) | catalogued as rs1416055722, COSV57297742; called by muse, mutect2
- DMRT1 | c.1008C>T p.S336= | Silent (SNP) | VAF 29/293 reads (10%) | catalogued as rs762527500; called by muse, mutect2, varscan2
- DNAH11 | c.4890C>T p.F1630= | Silent (SNP) | VAF 42/367 reads (11%) | catalogued as rs569494115, COSV60945336; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH14 | c.8523C>T p.F2841= (on ENST00000445597; = p.F3644= on NM_001367479.1) | Silent (SNP) | VAF 37/300 reads (12%) | catalogued as COSV59895258; called by muse, mutect2, varscan2
- DNAH7 | c.10818C>T p.F3606= | Silent (SNP) | VAF 22/422 reads (5%) | catalogued as COSV100413779; called by muse, mutect2
- DOCK2 | c.144C>T p.Y48= | Silent (SNP) | VAF 35/311 reads (11%) | called by muse, mutect2, varscan2
- DOCK7 | c.5268A>G p.V1756= (on ENST00000635253 / NM_001367561.1; = p.V1725= on NM_033407.3) | Silent (SNP) | VAF 51/273 reads (19%) | catalogued as rs780422344; called by muse, mutect2, varscan2
- DPEP3 | c.96C>T p.P32= | Silent (SNP) | VAF 45/404 reads (11%) | catalogued as rs1425325280, COSV99262562; called by muse, varscan2
- DSP | c.3594C>T p.H1198= | Silent (SNP) | VAF 50/425 reads (12%) | called by muse, mutect2, varscan2
- DUOX2 | c.3915C>T p.I1305= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as rs369478399; called by muse, mutect2, varscan2
- DYNC2H1 | c.1065C>T p.I355= | Silent (SNP) | VAF 31/315 reads (10%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1785G>A p.K595= | Silent (SNP) | VAF 73/451 reads (16%) | called by muse, mutect2, varscan2
- EPG5 | c.7371G>A p.V2457= | Silent (SNP) | VAF 18/332 reads (5%) | catalogued as rs1292285233; called by muse, mutect2
- ERCC2 | c.1857C>T p.I619= | Silent (SNP) | VAF 38/368 reads (10%) | catalogued as rs1486564629; called by muse, mutect2, varscan2
- ESRP2 | c.1422G>A p.R474= (on ENST00000565858 / NM_001365264.1; = p.R464= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/466 reads (15%) | catalogued as COSV99251332; called by muse, mutect2, varscan2
- FAM149A | c.1461G>A p.Q487= (on ENST00000356371 / NM_001367768.2; = p.Q196= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- FAM205A | c.930C>T p.L310= | Silent (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- FAM53C | c.627C>T p.S209= | Silent (SNP) | VAF 64/455 reads (14%) | called by muse, mutect2, varscan2
- FBXO4 | c.174C>T p.T58= | Silent (SNP) | VAF 103/348 reads (30%) | catalogued as rs946075051; called by muse, mutect2, varscan2
- FGF5 | c.96C>T p.P32= | Silent (SNP) | VAF 49/366 reads (13%) | called by muse, mutect2, varscan2
- FGF6 | c.612C>T p.F204= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as COSV57403697; called by muse, mutect2
- FKBP8 | c.936G>A p.K312= (on ENST00000222308 / NM_001308373.2; = p.K313= on NM_012181.5) | Silent (SNP) | VAF 33/216 reads (15%) | catalogued as rs1402021803; called by muse, mutect2, varscan2
- FMNL2 | c.2457G>A p.K819= | Silent (SNP) | VAF 60/349 reads (17%) | catalogued as COSV56504433; called by muse, mutect2, varscan2
- FMO2 | c.1011C>T p.F337= | Silent (SNP) | VAF 40/363 reads (11%) | called by muse, mutect2, varscan2
- FNDC1 | c.2382G>A p.R794= | Silent (SNP) | VAF 52/363 reads (14%) | called by muse, mutect2, varscan2
- FRAS1 | c.9846G>A p.K3282= | Silent (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- FRG2C | c.147C>T p.S49= | Silent (SNP) | VAF 32/954 reads (3%) | called by muse, mutect2
- FSTL5 | c.1368T>A p.V456= | Silent (SNP) | VAF 32/214 reads (15%) | called by muse, mutect2, varscan2
- FUBP3 | c.534C>T p.I178= | Silent (SNP) | VAF 30/217 reads (14%) | called by muse, mutect2, varscan2
- GABRQ | c.690C>T p.I230= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as COSV64782747; called by muse, mutect2, varscan2
- GIPC3 | c.2946G>A p.R982= | Silent (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2
- GRID1 | c.1281G>A p.E427= | Silent (SNP) | VAF 17/328 reads (5%) | catalogued as COSV60040751; called by muse, mutect2
- GRM7 | c.852G>A p.V284= | Silent (SNP) | VAF 28/334 reads (8%) | catalogued as COSV63130727; called by muse, mutect2
- GRWD1 | c.75T>C p.S25= | Silent (SNP) | VAF 61/426 reads (14%) | called by muse, mutect2, varscan2
264 further variants in this file (0 protein-altering or splice-affecting, 224 silent, 40 other) are not listed here.
